Somatic mutation profile of tumor specimen TCGA-KK-A6E7-01A (aliquot TCGA-KK-A6E7-01A-11D-A31L-08) from TCGA case TCGA-KK-A6E7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 46.7 years (17,074 days).
Specimen TCGA-KK-A6E7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8416eef-7e76-464e-ac2f-241807cf6f55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E7-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E7-11A-11D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/840bba4d-c6d6-4974-835a-cfdea688204b

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 13/29 reads (45%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AKR1D1 | c.478G>C p.A160P | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54337155, COSV54337984; called by muse, mutect2, varscan2
- ATG2A | c.3809G>A p.C1270Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); catalogued as COSV65967117; called by muse, mutect2, varscan2
- C19orf47 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.163); catalogued as COSV63509413; called by muse, mutect2, varscan2
- CA10 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780641204, COSV53353383; called by muse, mutect2, varscan2
- CPEB3 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV56457433; called by muse, mutect2, varscan2
- DCAF12L2 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63582112; called by muse, mutect2, varscan2
- ELOA2 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1472483563, COSV55300858; called by muse, mutect2, varscan2
- FAT2 | c.6752G>C p.G2251A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55821351; called by muse, mutect2, varscan2
- HTR1F | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.936); catalogued as rs867143226; called by muse, mutect2
- KIF1A | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760325615, COSV57491717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH5 | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as COSV71301786; called by muse, mutect2, varscan2
- MUC16 | c.29483C>T p.S9828F | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.155); catalogued as rs1193367378, COSV67472131; called by muse, mutect2, varscan2
- MUC16 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs1053083532, COSV67443227, COSV67472140; called by muse, mutect2
- NIPBL | c.6043A>G p.I2015V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as COSV56953602; called by muse, mutect2, varscan2
- PI4KB | c.669G>A p.M223I (on ENST00000368873 / NM_001369623.1; = p.M235I on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV55018072; called by muse, mutect2, varscan2
- RPS6KA1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64810045; called by muse, mutect2, varscan2
- TTN | c.30857T>C p.V10286A (on ENST00000591111; = p.V9359A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/221 reads (7%) | PolyPhen benign (0.006); catalogued as COSV60115431; called by muse, mutect2
- XPNPEP2 | c.1760C>G p.T587S | Missense Mutation (SNP) | VAF 57/75 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV64369285, COSV64370541; called by muse, mutect2, varscan2
- SPATA31A1 | c.3996C>G p.S1332R | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- TBCD | c.3567dup p.G1190Wfs*23 | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | called by mutect2, varscan2
- KCNA3 | c.150G>A p.P50= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV63901793; called by muse, mutect2, varscan2
- LRRIQ1 | c.2232C>T p.A744= | Silent (SNP) | VAF 109/357 reads (31%) | catalogued as COSV67832089; called by muse, mutect2, varscan2
- SBSN | c.348C>T p.G116= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV71733279; called by muse, mutect2
- SPDYE3 | c.679C>T p.L227= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs1349038360, COSV60107371; called by muse, mutect2, varscan2
- TNFAIP1 | c.96C>A p.L32= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV56876921; called by muse, mutect2, varscan2
- USB1 | c.192C>T p.S64= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as COSV54622460; called by muse, mutect2, varscan2
- WRNIP1 | c.1032C>T p.H344= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs766348656, COSV66356120; called by muse, mutect2, varscan2
